Somatic mutation profile of tumor specimen TCGA-CN-6023-01A (aliquot TCGA-CN-6023-01A-11D-1683-08) from TCGA case TCGA-CN-6023, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 73.3 years (26,769 days).
Specimen TCGA-CN-6023-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40d0c9a8-9e6c-4fcd-a0e1-40e9c4226c51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-6023-10A (Blood Derived Normal), aliquot TCGA-CN-6023-10A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80f7aa5a-6781-4faf-bcaf-b0bc8c556a5a

The open-access MAF lists 108 somatic variants for this specimen: 87 protein-altering or splice-affecting, 18 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 18, Nonsense Mutation 5, Splice Site 3, In Frame Del 3, 5'Flank 1, Frame Shift Ins 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HADHA | c.677-1G>A p.X226_splice | Splice Site (SNP) | VAF 24/135 reads (18%) | catalogued as rs1553314070, COSV101023723; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADIPOR1 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100579374; called by muse, mutect2, varscan2
- AKR1B1 | c.257A>G p.K86R | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.082); catalogued as COSV99605139; called by muse, mutect2
- ANKRD26 | c.2587A>T p.R863W | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.322); catalogued as COSV101062906; called by muse, mutect2, varscan2
- ARHGEF40 | c.1178G>T p.R393L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.474); catalogued as COSV100069956; called by muse, mutect2, varscan2
- ATP13A4 | c.1754C>G p.A585G | Missense Mutation (SNP) | VAF 26/357 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV99794000; called by muse, mutect2
- ATR | c.7910A>G p.Y2637C | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53813970; called by muse, mutect2, varscan2
- BCORL1 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.572); catalogued as rs758819764, COSV99498368; called by muse, mutect2, varscan2
- BMI1 | c.844C>A p.P282T | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV100936294, COSV64958743; called by muse, mutect2, varscan2
- CCDC57 | c.1769A>G p.K590R | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100492379; called by muse, mutect2, varscan2
- CHD6 | c.7178C>G p.P2393R | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV100950526; called by muse, mutect2, varscan2
- CHST9 | c.536G>T p.R179M | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99409578; called by muse, mutect2, varscan2
- CLUH | c.817G>A p.A273T (on ENST00000435359; = p.A311T on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.371); catalogued as rs200340260; called by muse, mutect2
- COL21A1 | c.2731G>C p.D911H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.606); catalogued as COSV99777295; called by muse, mutect2, varscan2
- COX18 | c.583G>T p.A195S | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as rs867305620, COSV99886927; called by muse, mutect2, varscan2
- CSMD1 | c.4267C>T p.Q1423* (on ENST00000520002; = p.Q1422* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | catalogued as COSV100143244, COSV99064855; called by muse, mutect2, varscan2
- DAAM1 | c.1705C>G p.L569V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as COSV100658109; called by muse, mutect2, varscan2
- DYNLRB2 | c.80-1G>C p.X27_splice | Splice Site (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100009626; called by muse, mutect2, varscan2
- ECT2L | c.2644G>A p.E882K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV99238377; called by muse, mutect2, varscan2
- FZD1 | c.982G>C p.V328L | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as COSV99842357; called by muse, mutect2, varscan2
- GCC2 | c.2430G>C p.E810D | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100565240; called by muse, mutect2, varscan2
- GSTO1 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV100086571; called by muse, mutect2, varscan2
- GTF3C1 | c.6298G>A p.E2100K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs759721942, COSV62238718; called by muse, mutect2, varscan2
- HIVEP1 | c.5575G>A p.E1859K | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.82); catalogued as COSV101044647, COSV65100769; called by muse, mutect2, varscan2
- HTR5A | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs371035945, COSV55287169; called by muse, mutect2, varscan2
- IHO1 | c.667A>G p.N223D | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99605792; called by muse, mutect2, varscan2
- ITGB8 | c.1616G>T p.G539V | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99750497; called by muse, mutect2, varscan2
- KLHDC10 | c.647A>G p.N216S | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs758908451, COSV100110846; called by muse, mutect2, varscan2
- KLHL7 | c.881G>A p.R294H (on ENST00000339077 / NM_001031710.3; = p.R246H on NM_018846.5) | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs1043587892, COSV59165446; called by muse, mutect2, varscan2
- KLRC4 | c.463A>G p.I155V | Missense Mutation (SNP) | VAF 63/182 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100511237; called by muse, mutect2, varscan2
- KMT2C | c.7625C>T p.S2542L | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs1432874243, COSV100066226, COSV51425272; called by muse, mutect2, varscan2
- LMCD1 | c.308A>G p.N103S | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.698); catalogued as COSV99337226; called by muse, mutect2
- LRCH3 | c.1666G>C p.V556L | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.03); catalogued as COSV100604942; called by muse, mutect2, varscan2
- LRFN5 | c.398A>G p.N133S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1171921446, COSV99982429; called by muse, mutect2, varscan2
- LY6H | c.318G>C p.E106D | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV100713840; called by muse, mutect2
- MAGEB1 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 5/13 reads (38%) | catalogued as COSV100974828, COSV66775600; called by muse, mutect2, varscan2
- MAGEB6 | c.262G>T p.G88C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.934); catalogued as COSV100983650; called by muse, mutect2, varscan2
- MASP1 | c.6-2A>T p.X2_splice | Splice Site (SNP) | VAF 14/55 reads (25%) | catalogued as COSV99396743; called by muse, mutect2
- MAX | c.273G>C p.Q91H | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV99408327; called by muse, mutect2, varscan2
- MGA | c.3070C>G p.L1024V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1277465034, COSV99578398; called by mutect2, varscan2
- MINK1 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs780528504, COSV100766981; called by muse, mutect2, varscan2
- MMP2 | c.1129A>G p.T377A | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV99527390; called by muse, mutect2, varscan2
- MRPS22 | c.451G>A p.E151K (on ENST00000310776 / NM_001363893.1; = p.E152K on NM_020191.4) | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV100168951; called by muse, mutect2, varscan2
- MYO1D | c.724A>G p.N242D | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.05); catalogued as COSV100553405; called by muse, mutect2, varscan2
- NFKBIB | c.982_984del p.D328del | In Frame Del (DEL) | VAF 18/76 reads (24%) | catalogued as rs770289700; called by pindel, varscan2
- NMNAT1 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101020373; called by muse, mutect2, varscan2
- OBSCN | c.19968C>G p.S6656R | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100800939; called by muse, mutect2
- OBSCN | c.19970T>G p.L6657R | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100800942; called by muse, mutect2
- OR2C1 | c.812G>A p.G271D | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs757066340, COSV100514835; called by mutect2, varscan2
- OTOGL | c.552C>G p.F184L (on ENST00000547103; = p.F175L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV101509014; called by muse, mutect2
- PA2G4 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as COSV100306288; called by muse, mutect2, varscan2
- PHF12 | c.811G>T p.V271F | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52018668, COSV99255433; called by muse, mutect2, varscan2
- PTPN2 | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV100518315; called by muse, mutect2, varscan2
- PURB | c.655C>T p.L219F | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101194887; called by muse, mutect2, varscan2
- PURB | c.654G>T p.E218D | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV101194889; called by muse, varscan2
- RAD50 | c.745G>T p.D249Y | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as COSV99528573; called by muse, mutect2
- RAI14 | c.1651G>C p.E551Q | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.601); catalogued as COSV99461788; called by muse, mutect2
- RASA1 | c.1817T>A p.L606H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99169596; called by muse, varscan2
- RFFL | c.157C>G p.H53D | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.451); catalogued as COSV99265148; called by muse, mutect2, varscan2
- RIC1 | c.3979G>C p.D1327H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99316606; called by muse, mutect2
- RNF133 | c.428T>G p.F143C | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV100411418; called by muse, mutect2, varscan2
- SEC23B | c.1125G>T p.M375I | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV99357368; called by muse, mutect2
- SEC24B | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.115); catalogued as COSV99492828; called by muse, mutect2, varscan2
- SHOC2 | c.305C>G p.S102* | Nonsense Mutation (SNP) | VAF 17/86 reads (20%) | catalogued as COSV99509875; called by muse, mutect2, varscan2
- SI | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as rs780700001, COSV100013830, COSV52297611; called by muse, mutect2
- SIL1 | c.520C>G p.L174V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV99497662; called by muse, mutect2, varscan2
- SLC12A6 | c.70G>C p.D24H | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.579); catalogued as COSV100825057; called by muse, mutect2, varscan2
- SLC9A2 | c.1890G>C p.E630D | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.422); catalogued as COSV99295815; called by muse, mutect2
- SLITRK4 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.953); catalogued as rs1166723245, COSV62022486, COSV62023994, COSV62025718; called by muse, mutect2, varscan2
- SMC1A | c.2940G>C p.E980D | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.534); catalogued as COSV100447000; called by muse, mutect2
- SPTB | c.4586G>T p.G1529V | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.775); catalogued as COSV101071968; called by muse, mutect2, varscan2
- TAZ | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100173231; called by muse, mutect2, varscan2
- TRIM68 | c.420G>C p.E140D | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs766374248, COSV100331607; called by muse, mutect2, varscan2
- TRRAP | c.4277A>T p.H1426L | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as COSV100721937; called by muse, mutect2, varscan2
- VCP | c.1796G>A p.R599Q | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV100734081; called by muse, mutect2, varscan2
- VCP | c.1118A>T p.D373V | Missense Mutation (SNP) | VAF 12/239 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100734083; called by muse, mutect2
- XKRX | c.1021G>T p.D341Y | Missense Mutation (SNP) | VAF 65/134 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV60708724; called by muse, mutect2, varscan2
- ZFC3H1 | c.467G>T p.R156L | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.257); catalogued as COSV100350319; called by muse, mutect2, varscan2
- ZFPM2 | c.2320C>T p.Q774* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV101022962; called by muse, mutect2
- ZMYM6 | c.1114C>T p.Q372* | Nonsense Mutation (SNP) | VAF 15/68 reads (22%) | catalogued as COSV100593000; called by muse, mutect2, varscan2
- ZNF445 | c.2329C>G p.L777V | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV68538555; called by muse, mutect2, varscan2
- ZNF768 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV99411345; called by muse, mutect2, varscan2
- BMS1 | c.2486_2488del p.K829del | In Frame Del (DEL) | VAF 8/81 reads (10%) | called by pindel, varscan2
- CCL23 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TTN | c.53023dup p.I17675Nfs*3 (on ENST00000591111; = p.I10251Nfs*3 on NM_003319.4) | Frame Shift Ins (INS) | VAF 34/92 reads (37%) | called by mutect2, pindel, varscan2
- ZNF821 | c.1072_1077del p.K358_M359del (on ENST00000425432 / NM_001376297.1; = p.K316_M317del on NM_017530.2 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 9/57 reads (16%) | called by mutect2, pindel, varscan2
- A4GNT | c.786C>A p.P262= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV99367679; called by muse, mutect2, varscan2
- AGRN | c.3159G>A p.V1053= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV101038570; called by muse, mutect2, varscan2
- ALK | c.2418T>A p.R806= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as COSV101201121, COSV66574891; called by muse, mutect2, varscan2
- ALMS1 | c.8046A>G p.E2682= | Silent (SNP) | VAF 26/187 reads (14%) | catalogued as COSV100041046; called by muse, mutect2, varscan2
- COQ4 | c.330C>G p.L110= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV100306602; called by muse, mutect2, varscan2
- DMD | c.8643A>G p.L2881= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as rs747605156, COSV100625921; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- HNRNPL | c.1467G>A p.E489= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV99669933; called by muse, mutect2
- HNRNPUL1 | c.1638C>T p.T546= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as rs771581074, COSV54563131; called by muse, mutect2, varscan2
- KCNH3 | c.295C>T p.L99= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as COSV99234685; called by muse, mutect2
- MYOF | c.6120C>T p.F2040= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs772809321, COSV100825170; called by muse, mutect2
- MYSM1 | c.886C>T p.L296= | Silent (SNP) | VAF 14/130 reads (11%) | catalogued as COSV101284019; called by muse, mutect2, varscan2
- NCBP2L | c.51C>T p.S17= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV100966475; called by muse, mutect2, varscan2
- NDRG3 | c.798A>C p.A266= (on ENST00000349004 / NM_032013.4; = p.A254= on NM_022477.4) | Silent (SNP) | VAF 56/159 reads (35%) | catalogued as rs993760146, COSV100675308; called by muse, mutect2, varscan2
- NT5C1B | c.327G>A p.K109= (on ENST00000359846 / NM_001199086.2; = p.K49= on NM_033253.4) | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV100409773; called by muse, mutect2, varscan2
- PNPLA7 | c.2631C>T p.G877= | Silent (SNP) | VAF 6/13 reads (46%) | called by muse, varscan2
- RGS17 | c.126T>A p.T42= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV99242438; called by muse, mutect2, varscan2
- SLC25A41 | c.453C>A p.G151= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV100382881; called by muse, mutect2
- ZNF367 | c.852G>A p.Q284= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV99480616; called by muse, mutect2, varscan2
- PRPF4B | c.2581+167G>C | Intron (SNP) | VAF 75/142 reads (53%) | called by muse, mutect2, varscan2
- RHBG | chr1:156367748 C>A | 5'Flank (SNP) | VAF 16/102 reads (16%) | called by muse, mutect2, varscan2
- SNORD116-20 | n.12G>T | RNA (SNP) | VAF 17/108 reads (16%) | called by muse, mutect2, varscan2
